Surgical pathology report (de-identified scan), TCGA case TCGA-HF-7136, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Ontario Institute for Cancer Research (OICR), specimen TCGA-HF-7136-01A (Primary Tumor).

[page 1 of 3]
A description for each data field can be found in the 'Data description' worksheet (yellow tab).

Sample Collection Details						
Sample Number	Sample Type	Sample Preparation	Site of Tissue	Site of Primary (Event)	Year of Sample Collection	Age at Sample Collection (yrs)
	BUFFY	FF		GAST		
	TUMOUR	FF	GE junction	GAST		

[page 2 of 3]
Histology and staging								
Sample	Days to	Days to	Type of	Site of	Tumour	Histology	Grade/	Pathologic
Comments	Procedure	Diagnosis	Procedure	Primary	Size (cm)		Differentiat	al T
	Date			(Histology)			ion	
	■	■	RESECT	Gastric	5.5	Adenocarcinoma	II	T3
	■	■	RESECT	Gastric	5.5	Adenocarcinoma	II	T3

[page 3 of 3]
Pathologic al N	Clinical M	Histology Comments	Slide URL
N1	M0	The tumour infiltrates through the entire gastric and esophageal wall and is present in the adventitia.	
N1	M0	The tumour infiltrates through the entire gastric and esophageal wall and is present in the adventitia.	

Source: NCI Genomic Data Commons file 5ca2f197-ef45-46e2-9a3a-8e7229a4491a (TCGA-HF-7136.A190DF56-475D-4E78-949A-985E0F098ADC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).